Gene-level copy-number profile of tumor specimen BLGSP-71-06-00089-01B from CGCI case BLGSP-71-06-00089, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 5.2 years (1,909 days).
Specimen BLGSP-71-06-00089-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d10297ab-1785-4a58-9a72-eb0daa4f748e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00089-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/705f7ab6-e248-4277-8960-ca003b3a05ba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 181; copy number 1: 2,905; copy number 2: 55,309; copy number 3: 453; copy number 4: 26; copy number 5: 11; copy number 6: 2; copy number 7: 1.

Homozygous deletions (total copy number 0; autosomes only): 181 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 34 genes (within-gene range 0–3): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr15:20,759,311–20,775,998, 3 genes: AC012414.2, AC012414.3, LONRF2P3.
- chr22:22,738,944–22,896,111, 26 genes (within-gene range 0–1): IGLV3-17, IGLV3-16, IGLV3-15, IGLV3-13, IGLV3-12, AC244157.1, AC244157.2, IGLV2-11, AC245028.3, IGLV3-10, AC245028.1, IGLV3-9, IGLV2-8, MIR650, AC245028.2, IGLV3-7, IGLV3-6, IGLV2-5, IGLV3-4, IGLV4-3, IGLV3-2, IGLV3-1, MIR5571, IGLL5, IGLJ1, IGLC1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 14 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:20,803,505–20,866,314, 6 genes, copy number 5: AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P.
- chr15:20,901,441–20,901,609, 1 gene, copy number 7: ZNF519P2.
- chr15:21,298,233–21,325,241, 2 genes, copy number 5 (within-gene range 3–6): AC068446.2, RNU6-1235P.
- chr15:21,951,242–21,951,323, 1 gene, copy number 6: MIR5701-3.
- chr15:22,178,107–22,185,402, 2 genes, copy number 5: IGHV1OR15-3, IGHV4OR15-8.
- chr21:44,107,373–44,210,114, 2 genes, copy number 5–6 (within-gene range 2–6): PWP2, GATD3A.

Autosomal genes at a single copy (total copy number 1): 59. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
